TCGA case TCGA-KN-8426 — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b08dfba8-6afb-4217-9259-72be6f1f3363

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 50.2 years (18,345 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 108 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 108 days; Disease response: With Tumor.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Elevated.
- Calcium: Low.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KN-8426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.1; Shortest dimension: 0.5.
  Slide TCGA-KN-8426-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-KN-8426-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KN-8426-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KN-8426-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.5; Shortest dimension: 0.6.
  Slide TCGA-KN-8426-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Tobacco smoking history indicator: 1; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 108 days; disease-specific survival: no event (censored), 108 days; progression-free interval: no event (censored), 108 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KN-8426-01A-11D-2308-01): tumor purity 0.87, ploidy 1.53, whole-genome doublings 0.
